Somatic mutation profile of tumor specimen ALCH-B2V0-TTP1-A (aliquot ALCH-B2V0-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B2V0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 35.2 years (12,856 days).
Specimen ALCH-B2V0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13f2419c-fcf0-4fbe-8ae0-cc6380ff6d24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2V0-NB1-A (Blood Derived Normal), aliquot ALCH-B2V0-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06ff02d7-3a7e-4e6f-9952-2c97057f3a6f

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAGEC1 | c.1896C>G p.C632W | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.869); catalogued as COSV99596661; called by muse, mutect2
- RASAL1 | c.1859G>C p.R620P | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.977); catalogued as COSV99921766; called by muse, mutect2, varscan2
- CCDC116 | c.1531G>A p.A511T | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- CDH11 | c.241A>G p.I81V | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2
- FCGR2C | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 55/982 reads (6%) | SIFT tolerated (0.94); PolyPhen benign (0.145); called by muse, mutect2
- PIP5K1C | c.1067C>T p.T356M | Missense Mutation (SNP) | VAF 14/312 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PEG3 | c.3306T>C p.P1102= | Silent (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- SRCAP | c.8721C>A p.V2907= | Silent (SNP) | VAF 15/127 reads (12%) | called by muse, mutect2, varscan2
- TMEM43 | c.13-534T>A | Intron (SNP) | VAF 6/73 reads (8%) | called by muse, mutect2
